Gene-level copy-number profile of tumor specimen C3N-02282-05 from CPTAC case C3N-02282, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 63.6 years (23,227 days).
Specimen C3N-02282-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ffa5573a-6d9f-4831-8dd1-a83cb956ae61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02282-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,716 have no estimate.
https://portal.gdc.cancer.gov/files/e3d86fa4-09f2-4a19-b968-59c5bbe61f7a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 23; copy number 1: 14,323; copy number 2: 27,414; copy number 3: 14,128; copy number 4: 2,124; copy number 5: 863; copy number 6: 32.

Homozygous deletions (total copy number 0; autosomes only): 23 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:106,257,762–106,324,760, 14 genes (within-gene range 0–2): IGHV3-22, IGHVII-22-1, IGHVIII-22-2, IGHV3-23, IGHV1-24, HOMER2P2, LINC00226, IGHV3-25, IGHVIII-25-1, IGHV2-26, IGHVIII-26-1, IGHVII-26-2, IGHV7-27, IGHV4-28.
- chr14:106,421,711–106,422,218, 1 gene (within-gene range 0–2): IGHV4-39.
- chr14:106,436,415–106,461,055, 4 genes (within-gene range 0–2): AC244452.1, IGHVII-40-1, IGHV3-41, HOMER2P1.
- chr14:106,470,264–106,470,800, 1 gene (within-gene range 0–2): IGHV3-43.
- chr21:43,414,483–43,453,902, 2 genes: SIK1, LINC00319.
- chr21:43,465,309–43,467,298, 1 gene (within-gene range 0–1): AP001048.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 895 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:209,428,817–209,432,838, 2 genes, copy number 5: MIR205HG, MIR205.
- chr5:1,201,595–52,804,044, 666 genes, copy number 5–6 (within-gene range 1–7) (broad region; genes not listed).
- chr8:141,514,638–143,656,418, 72 genes, copy number 5 (broad region; genes not listed).
- chr8:143,915,153–144,605,816, 57 genes, copy number 5: PLEC, MIR661, PARP10, GRINA, SPATC1, SMPD5, OPLAH, MIR6846, AC109322.1, EXOSC4, MIR6847, GPAA1, CYC1, SHARPIN, MAF1, WDR97, HGH1, TSSK5P, MROH1, BOP1, MIR7112, SCX, HSF1, DGAT1, AC233992.1, MIR6848, SCRT1, SLC52A2, TMEM249, AC233992.2, FBXL6, ADCK5, CPSF1, MIR939, MIR1234, MIR6849, AC233992.3, SLC39A4, VPS28, TONSL, MIR6893, TONSL-AS1, CYHR1, AC084125.1, KIFC2, FOXH1, PPP1R16A, AC084125.2, GPT, MFSD3, RECQL4, AC084125.4, LRRC14, LRRC24, C8orf82, ARHGAP39, AC084125.3.
- chr9:74,371,335–74,384,578, 1 gene, copy number 6: AL355674.1.
- chr10:17,137,336–18,043,292, 20 genes, copy number 5: AC067747.1, TRDMT1, VIM-AS1, VIM, AL133415.1, ST8SIA6, ST8SIA6-AS1, Y_RNA, PRPF38AP2, HACD1, AC069542.2, STAM-AS1, STAM, AC069542.1, TMEM236, MRC1, MIR511, AC069023.1, SLC39A12, SLC39A12-AS1.
- chr13:29,509,414–29,595,688, 1 gene, copy number 5: SLC7A1.
- chr16:60,925,733–62,357,746, 9 genes, copy number 5: AC009169.1, RPS27AP16, CDH8, AC092125.1, RN7SKP76, AC012174.1, RNU6-21P, AC009161.2, AC009161.1.
- chr20:3,732,685–5,197,887, 44 genes, copy number 5: HSPA12B, C20orf27, SPEF1, CENPB, CDC25B, LINC01730, AL109804.1, AP5S1, MAVS, PANK2-AS1, PANK2, MIR103A2, MIR103B2, AL031670.1, RNF24, FTLP3, RPL21P2, AL356414.1, SMOX, LINC01433, ADRA1D, AL139350.1, AL121781.1, AL121916.1, RPS4XP2, PRNP, PRND, PRNT, IDI1P3, AL133396.1, RASSF2, SLC23A2, AL389886.1, AL121890.1, AL121890.3, AL121890.2, AL121890.5, AL121890.4, TMEM230, RNA5SP474, Y_RNA, PCNA, AL121924.1, CDS2.
- chr20:50,040,716–50,691,542, 23 genes, copy number 5: TRERNA1, UBE2V1, PEDS1-UBE2V1, PEDS1, LINC01275, AL161937.1, LINC01273, CEBPB-AS1, CEBPB, PELATON, LINC01270, LINC01271, RN7SL636P, COX6CP2, PTPN1, RN7SL672P, Y_RNA, AL133230.1, MIR645, RIPOR3, MIR1302-5, RPL36P2, RIPOR3-AS1.

Autosomal genes at a single copy (total copy number 1): 11,467. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
